Somatic mutation profile of tumor specimen TCGA-RW-A68C-01A (aliquot TCGA-RW-A68C-01A-11D-A35D-08) from TCGA case TCGA-RW-A68C, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.7 years (15,962 days).
Specimen TCGA-RW-A68C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77cbdc2d-cabf-41e7-afe2-ca897a30264f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68C-10A (Blood Derived Normal), aliquot TCGA-RW-A68C-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00e6557d-9213-4d77-9311-66939b656637

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OLFM3 | c.772G>A p.D258N (on ENST00000338858 / NM_001288821.1; = p.D238N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58804402; called by muse, mutect2
- PCYOX1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.18); catalogued as rs1393925654; called by muse, mutect2, varscan2
- PTPRD | c.4238C>A p.A1413D | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61939991; called by muse, mutect2
- SLC25A21 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1392165040, COSV58717920, COSV58733990; called by muse, mutect2, varscan2
- VCAM1 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54120006; called by muse, mutect2
- ADAM20 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.04); called by muse, mutect2
- BHLHE40 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LARP1 | c.2507T>A p.M836K (on ENST00000518297 / NM_033551.3; = p.M759K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
